Somatic mutation profile of tumor specimen TCGA-AG-3728-01A (aliquot TCGA-AG-3728-01A-01W-0899-10) from TCGA case TCGA-AG-3728, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 73.7 years (26,906 days).
Specimen TCGA-AG-3728-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0df97172-d835-4b89-a18e-bda83849ccfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3728-10A (Blood Derived Normal), aliquot TCGA-AG-3728-10A-01W-0901-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59532fa6-c9ac-4741-91a9-8337d629a678

The open-access MAF lists 114 somatic variants for this specimen: 92 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 20, Splice Site 5, Nonsense Mutation 4, Splice Region 2, Frame Shift Del 2, Intron 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 103/159 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANXA1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs752285742, COSV57412673; called by muse, mutect2, varscan2
- AP5M1 | c.818C>A p.T273N | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as rs1317854002; called by muse, mutect2, varscan2
- APC | c.4094del p.G1365Vfs*50 | Frame Shift Del (DEL) | VAF 38/99 reads (38%) | catalogued as CD972009; called by mutect2, pindel, varscan2
- BARHL1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs767294868, COSV55039139; called by muse, mutect2, varscan2
- BMP5 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 138/437 reads (32%) | catalogued as rs550837639, COSV63700675; called by muse, mutect2, varscan2
- CABP5 | c.238+1G>A p.X80_splice | Splice Site (SNP) | VAF 42/95 reads (44%) | catalogued as rs761490135; called by muse, mutect2, varscan2
- CLIP4 | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs756999943, COSV60753026; called by muse, mutect2, varscan2
- CNTN4 | c.2449G>C p.D817H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1559825695, COSV61872648; called by muse, mutect2, varscan2
- DNAH11 | c.10441G>A p.E3481K | Missense Mutation (SNP) | VAF 67/430 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs727502969, COSV60950892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFR3A | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs778434355, COSV54456225; called by muse, mutect2, varscan2
- ENAM | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200947570; called by muse, mutect2, varscan2
- FADS2 | c.167dup p.Q57Pfs*22 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | catalogued as rs771966661; called by pindel, varscan2
- FAM126A | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs962035406; called by muse, mutect2, varscan2
- FAM47A | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1224051046, COSV60497362; called by muse, mutect2, varscan2
- FAM53A | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs775759980, COSV100356790, COSV57401689; called by muse, mutect2, varscan2
- FEN1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs573495657, COSV57250794; called by muse, mutect2, varscan2
- FN1 | c.5894C>T p.P1965L | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs564645723; called by muse, mutect2, varscan2
- FRY | c.5372A>T p.K1791M | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV66580824; called by muse, mutect2
- GPR149 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67665860; called by muse, mutect2, varscan2
- GPR179 | c.4558G>A p.E1520K (on ENST00000621958; = p.E1519K on NM_001004334.4) | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.767); catalogued as rs201569873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2A | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs773569899, COSV58045765, COSV58056000; called by muse, mutect2, varscan2
- GRXCR1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs777472087, COSV67671604; called by muse, mutect2, varscan2
- IL1RAPL1 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV56303567; called by muse, mutect2
- ITIH5 | c.2242A>T p.I748F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as rs1483149427; called by muse, mutect2, varscan2
- KANK1 | c.2304del p.D768Efs*9 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as COSV63216500; called by mutect2, pindel, varscan2
- KCTD16 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as rs760934349, COSV72578873; called by muse, mutect2, varscan2
- KIAA1109 | c.10249G>T p.A3417S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV52684837, COSV52694158; called by muse, mutect2, varscan2
- LINGO2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs866067533, COSV58064896; called by muse, mutect2, varscan2
- LRP2 | c.8334G>T p.R2778S | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.92); catalogued as COSV55558403; called by muse, mutect2, varscan2
- LRRC4C | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs778049301; called by muse, mutect2, varscan2
- MAGEC3 | c.1879G>T p.A627S | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1004389424, COSV68924378; called by muse, mutect2, varscan2
- METTL2A | c.496A>C p.S166R | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.37); PolyPhen benign (0.068); catalogued as COSV100274328; called by mutect2, varscan2
- METTL2B | c.496A>C p.S166R | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.328); catalogued as COSV52309011, COSV52311171; called by muse, varscan2
- MORN1 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs142639415; called by muse, mutect2
- MRC1 | c.3985C>T p.R1329W | Missense Mutation (SNP) | VAF 444/1456 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); catalogued as rs782546027; called by muse, mutect2, varscan2
- MRPS5 | c.902C>A p.T301K | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55533737; called by muse, mutect2, varscan2
- MYCBP2 | c.6838dup p.M2280Nfs*26 (on ENST00000357337; = p.M2318Nfs*26 on NM_015057.5) | Frame Shift Ins (INS) | VAF 20/138 reads (14%) | catalogued as rs776222254; called by mutect2, varscan2
- NAA15 | c.2344C>T p.R782* | Nonsense Mutation (SNP) | VAF 31/108 reads (29%) | catalogued as COSV56718689; called by muse, mutect2, varscan2
- NDN | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); catalogued as rs1444200451, COSV100086437; called by muse, mutect2
- NF1 | c.5426C>T p.P1809L (on ENST00000358273 / NM_001042492.3; = p.P1788L on NM_000267.3) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs587782220, COSV62215866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPY2R | c.398C>A p.A133E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1224035244; called by muse, mutect2, varscan2
- NRXN1 | c.2054G>A p.C685Y | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58496389; called by muse, mutect2, varscan2
- NUP88 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs1356281384, COSV52584703; called by muse, varscan2
- OLIG3 | c.268G>C p.G90R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs778999155, COSV62989238; called by mutect2, varscan2
- OR5K2 | c.782G>C p.R261T | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV71143244, COSV71143538; called by muse, mutect2, varscan2
- PIGU | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs757337483, COSV54166771; called by muse, mutect2, varscan2
- PLA2G4A | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV66553306; called by muse, mutect2, varscan2
- PPP1R2 | c.388T>A p.S130T | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.033); catalogued as rs1387664753, COSV60498664; called by muse, mutect2, varscan2
- RALYL | c.366C>T p.G122= | Splice Region (SNP) | VAF 60/323 reads (19%) | catalogued as rs182622234, COSV72818112; called by muse, mutect2, varscan2
- RCC1 | c.660C>T p.L220= | Splice Region (SNP) | VAF 7/9 reads (78%) | catalogued as rs778491374; called by muse, mutect2, varscan2
- RPGRIP1 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs376493676; called by muse, mutect2, varscan2
- RYR1 | c.9202C>A p.L3068I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV100616021; called by muse, mutect2, varscan2
- SI | c.1716-1G>A p.X572_splice | Splice Site (SNP) | VAF 54/179 reads (30%) | catalogued as rs746602450, COSV100016270, COSV52303821; called by muse, mutect2, varscan2
- SIM1 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 80/492 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs1334153580, COSV99492209; called by muse, varscan2
- SLC4A1 | c.1471G>A p.V491M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs757478694; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SOBP | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as rs1307021878, COSV58003164; called by muse, mutect2
- SPTBN2 | c.3799G>A p.A1267T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100017859, COSV100020835; called by muse, mutect2
- TP53BP2 | c.1385C>T p.P462L (on ENST00000343537 / NM_001031685.3; = p.P333L on NM_005426.2) | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs774631779; called by muse, mutect2, varscan2
- TRPM6 | c.2578G>A p.V860M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62504417; called by muse, mutect2, varscan2
- ZNF37A | c.239-1G>C p.X80_splice | Splice Site (SNP) | VAF 41/236 reads (17%) | catalogued as COSV61074087, COSV61075650; called by muse, mutect2, varscan2
- ZSWIM3 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs766108911, COSV54851856; called by muse, mutect2, varscan2
- ABL1 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRIP | c.944T>C p.L315P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CCDC86 | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- DNAH8 | c.2384-1G>C p.X795_splice | Splice Site (SNP) | VAF 43/414 reads (10%) | called by muse, mutect2, varscan2
- DSG2 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- FAM133A | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FBXO30 | c.623G>A p.G208D | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- FBXW7 | c.584G>T p.S195I (on ENST00000281708 / NM_001349798.2; = p.S115I on NM_018315.5) | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- GSPT2 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- HEATR9 | c.301A>C p.K101Q | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HTR2C | c.1172A>G p.K391R | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- IFIH1 | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- KANK2 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2
- LPGAT1 | c.1024T>G p.L342V | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1B | c.10200A>T p.Q3400H | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTSS1 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- MYOCD | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAF1 | c.1009C>T p.L337F | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKX6-1 | c.718A>T p.R240* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- NXN | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 67/90 reads (74%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OSER1 | c.226A>G p.T76A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PIH1D2 | c.548-2A>T p.X183_splice | Splice Site (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- RBBP6 | c.1924T>C p.Y642H | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR2 | c.8236A>G p.I2746V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERGEF | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM132D | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TPTE | c.1574G>A p.R525K (on ENST00000618007 / NM_199261.4; = p.R507K on NM_199259.4) | Missense Mutation (SNP) | VAF 38/617 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- WDR72 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZBTB24 | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 123/164 reads (75%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H14 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CYP26B1 | c.315C>A p.I105= | Silent (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- DNM2 | c.207C>G p.L69= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV58957774; called by muse, mutect2, varscan2
- DOCK10 | c.6450G>A p.T2150= | Silent (SNP) | VAF 51/243 reads (21%) | catalogued as rs754401157, COSV51428667; called by muse, mutect2, varscan2
- GRIK3 | c.642G>A p.S214= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs141315852; called by muse, mutect2, varscan2
- KBTBD6 | c.1705T>C p.L569= | Silent (SNP) | VAF 64/434 reads (15%) | called by muse, varscan2
- KIF4A | c.1293C>T p.N431= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as rs370260378, COSV65541390; called by muse, mutect2, varscan2
- KLC4 | c.1635C>T p.G545= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- KRT33B | c.810G>A p.A270= | Silent (SNP) | VAF 103/139 reads (74%) | catalogued as rs760179357, COSV52442538; called by muse, mutect2, varscan2
- MYO1B | c.150T>C p.S50= | Silent (SNP) | VAF 34/438 reads (8%) | called by muse, mutect2
- NMBR | c.306G>A p.S102= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs544695044, COSV57801965; called by muse, mutect2, varscan2
- PCDHA13 | c.1338C>T p.A446= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as rs782093980, COSV56547201; called by muse, mutect2, varscan2
- PCDHGA9 | c.429C>T p.N143= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs1022563452, COSV53899236; called by muse, mutect2, varscan2
- PRAMEF10 | c.1242C>T p.A414= | Silent (SNP) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- RBM10 | c.2709C>T p.G903= | Silent (SNP) | VAF 47/56 reads (84%) | called by muse, mutect2, varscan2
- RXFP3 | c.1134G>A p.A378= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV57508383; called by muse, mutect2, varscan2
- SLFN11 | c.2052A>G p.A684= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as COSV57699662; called by muse, mutect2, varscan2
- ST3GAL1 | c.939G>A p.T313= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs200642820, COSV60611464, COSV60612463; called by muse, mutect2, varscan2
- TRPA1 | c.339C>T p.S113= | Silent (SNP) | VAF 35/170 reads (21%) | catalogued as rs553282808, COSV100082781; called by muse, mutect2, varscan2
- ZNF236 | c.4692C>T p.D1564= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1223999673, COSV53498339; called by muse, mutect2, varscan2
- ZW10 | c.1899A>G p.L633= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as COSV52319660; called by muse, mutect2
- AK9 | c.3633+13del | Intron (DEL) | VAF 10/98 reads (10%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23887T>C | Intron (SNP) | VAF 143/530 reads (27%) | catalogued as COSV67450615; called by muse, varscan2
